Somatic mutation profile of tumor specimen TCGA-HU-8608-01A (aliquot TCGA-HU-8608-01A-11D-2394-08) from TCGA case TCGA-HU-8608, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.6 years (25,789 days).
Specimen TCGA-HU-8608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb31a824-53a0-438d-98c1-f426f08245ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8608-10A (Blood Derived Normal), aliquot TCGA-HU-8608-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fc02096-a234-4e9d-a18b-933465a39784

The open-access MAF lists 99 somatic variants for this specimen: 76 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 22, Nonsense Mutation 6, Splice Site 4, Frame Shift Ins 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2048G>C p.R683T | Missense Mutation (SNP) | VAF 478/754 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519722, COSV67581394, COSV67592547, COSV67612512; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 22/136 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs374634800; called by muse, mutect2, varscan2
- ABHD10 | c.262A>G p.M88V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56325132; called by muse, mutect2, varscan2
- AFDN | c.2939A>G p.Y980C | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV60044276; called by muse, mutect2, varscan2
- AJM1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56032976; called by muse, mutect2, varscan2
- ALDH3A2 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51566699; called by muse, mutect2, varscan2
- ALG10B | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.119); catalogued as COSV58143260; called by muse, mutect2, varscan2
- APPL2 | c.694A>G p.M232V | Missense Mutation (SNP) | VAF 68/490 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as rs373794263; called by muse, mutect2, varscan2
- ARID1A | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV61377473; called by muse, mutect2, varscan2
- ASGR2 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54690205; called by muse, mutect2, varscan2
- BCOR | c.4173+2T>C p.X1391_splice (on ENST00000378444 / NM_001123385.2; = p.X1357_splice on NM_017745.6) | Splice Site (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100654191, COSV60706913; called by muse, mutect2, varscan2
- BRINP3 | c.1629G>C p.K543N | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV66523943; called by muse, mutect2, varscan2
- CARF | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100247502, COSV57547630; called by mutect2, varscan2
- CHD2 | c.2977A>G p.M993V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as COSV67709187; called by muse, mutect2
- CLEC12A | c.531+1G>A p.X177_splice | Splice Site (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100429746, COSV58561287; called by muse, mutect2, varscan2
- CSMD1 | c.4208G>A p.R1403H (on ENST00000520002; = p.R1402H on NM_033225.6) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758153692, COSV59277963; called by muse, mutect2, varscan2
- CSPG4 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs573119481, COSV57894893; called by muse, mutect2, varscan2
- CTTNBP2 | c.4139C>T p.P1380L | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50401226; called by muse, mutect2, varscan2
- DNAJC18 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV57415813; called by muse, mutect2, varscan2
- DPRX | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV64949455; called by muse, mutect2, varscan2
- DPYSL4 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs1209652975, COSV53840650; called by muse, mutect2, varscan2
- E2F8 | c.628A>T p.K210* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | catalogued as COSV51463387; called by muse, mutect2, varscan2
- ENTPD7 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65112278; called by muse, mutect2, varscan2
- EPX | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs903413866, COSV56596381, COSV56596604; called by muse, mutect2, varscan2
- FAM171B | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59003446; called by muse, mutect2, varscan2
- FAM184A | c.1954C>G p.L652V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV58854322; called by muse, mutect2, varscan2
- FCGBP | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.184); catalogued as rs1437897345; called by muse, mutect2, varscan2
- FRY | c.5869G>T p.G1957* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV66570070, COSV66576551; called by muse, mutect2
- GRID1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs371004026, COSV60048457, COSV60059690; called by muse, mutect2, varscan2
- HERC6 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369219414; called by muse, mutect2, varscan2
- HS3ST3B1 | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100714505; called by muse, mutect2, varscan2
- KBTBD6 | c.97T>C p.F33L | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV65271270; called by muse, mutect2, varscan2
- KCND2 | c.1436A>G p.H479R | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.836); catalogued as rs745746548, COSV58579733; called by muse, mutect2, varscan2
- MFSD10 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs369064197; called by muse, mutect2
- MRPL17 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV56618374; called by muse, mutect2, varscan2
- MTA1 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58757272; called by muse, mutect2, varscan2
- MUC16 | c.27727G>T p.A9243S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV67465209; called by muse, mutect2, varscan2
- NFX1 | c.1282A>C p.N428H | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV59310246; called by muse, mutect2, varscan2
- NPAP1 | c.1904T>C p.F635S | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.322); catalogued as COSV61506897; called by muse, mutect2, varscan2
- NR3C1 | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 41/141 reads (29%) | catalogued as COSV51542766; called by muse, mutect2, varscan2
- NR4A2 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59893705; called by muse, mutect2, varscan2
- OR4D2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as rs1218412877, COSV73459763; called by muse, mutect2, varscan2
- OR52H1 | c.754A>T p.M252L (on ENST00000322653; = p.M258L on NM_001005289.1) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs753147468, COSV59505368; called by muse, mutect2, varscan2
- OSBP | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 80/396 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416181943, COSV55662556; called by muse, mutect2, varscan2
- PAMR1 | c.302dup p.T102Yfs*4 | Frame Shift Ins (INS) | VAF 84/480 reads (18%) | catalogued as rs751755759; called by mutect2, varscan2
- PGPEP1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV53252354; called by muse, mutect2, varscan2
- PHF24 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs780590212, COSV54273347; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs749921656, COSV53452800; called by muse, mutect2, varscan2
- RAPSN | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as COSV54084448; called by muse, mutect2, varscan2
- ROCK2 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.092); catalogued as COSV55078655, COSV99836990; called by muse, mutect2, varscan2
- RPS3 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53704729; called by muse, mutect2, varscan2
- SCN8A | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.879); catalogued as rs765763546, COSV61981429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFPQ | c.848C>G p.S283C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61758659, COSV61758956; called by mutect2, varscan2
- SLC11A1 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1416225319, COSV51917039; called by muse, mutect2, varscan2
- SLC12A4 | c.2577G>T p.M859I | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs761019274, COSV50452774; called by muse, mutect2, varscan2
- SLC25A31 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs773420489, COSV55419202; called by muse, mutect2, varscan2
- SLCO6A1 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1561462106, COSV65808126, COSV65809657; called by mutect2, varscan2
- SLF1 | c.2641G>A p.D881N | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748321691, COSV54369958; called by muse, mutect2, varscan2
- SPAG17 | c.3251A>G p.K1084R | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60458661; called by muse, mutect2, varscan2
- STAT1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV63116067; called by muse, mutect2, varscan2
- SYNE2 | c.5011T>A p.L1671I | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV59950744; called by muse, mutect2, varscan2
- TCHH | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs756725239, COSV64274746; called by muse, varscan2
- TTN | c.67361G>T p.R22454M (on ENST00000591111; = p.R15030M on NM_003319.4) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | PolyPhen benign (0.255); catalogued as COSV59886710, COSV60052834; called by muse, mutect2, varscan2
- USP42 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV60360108; called by muse, mutect2
- WFIKKN2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs201815741; called by muse, mutect2, varscan2
- WNK1 | c.3005A>G p.N1002S | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV60032912; called by muse, mutect2, varscan2
- ZFHX4 | c.2022T>A p.C674* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV50787848; called by muse, mutect2, varscan2
- ZNF835 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV73379341, COSV73379433; called by muse, mutect2, varscan2
- ZYG11B | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV53752908; called by muse, mutect2, varscan2
- IHO1 | c.56+3_56+7dup p.X19_splice | Splice Site (INS) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- MARF1 | c.41_48del p.T14Mfs*6 | Frame Shift Del (DEL) | VAF 34/319 reads (11%) | called by mutect2, pindel, varscan2
- PDE5A | c.1908_1909dup p.K637Tfs*3 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- PLK1 | c.1555del p.S519Afs*28 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- VPS4A | c.1212+3_1212+6del p.X404_splice | Splice Site (DEL) | VAF 25/160 reads (16%) | called by mutect2, pindel, varscan2
- ABCC11 | c.2598C>T p.Y866= | Silent (SNP) | VAF 39/177 reads (22%) | catalogued as rs745928898, COSV62323029; called by muse, mutect2, varscan2
- ARFGEF3 | c.4593C>T p.H1531= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs145838885; ClinVar: likely benign; called by muse, mutect2, varscan2
- CUBN | c.4725C>A p.S1575= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV64708115, COSV64715477; called by muse, mutect2, varscan2
- DSCAML1 | c.2235C>T p.I745= (on ENST00000321322; = p.I685= on NM_020693.4) | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs1253066932, COSV58390414; called by muse, mutect2, varscan2
- ESRP1 | c.471C>T p.D157= | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as rs376259698, COSV64408300; called by muse, mutect2, varscan2
- FBLN7 | c.684T>C p.C228= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV55616202; called by muse, mutect2, varscan2
- LAMB2 | c.4389G>T p.L1463= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV59733407; called by muse, mutect2, varscan2
- LCMT2 | c.1323T>C p.S441= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as COSV59790379; called by muse, mutect2, varscan2
- OBSCN | c.8229G>A p.K2743= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV52773323; called by muse, mutect2, varscan2
- PCDHA13 | c.2046G>A p.A682= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV56500528; called by muse, mutect2, varscan2
- PCDHGB6 | c.2106C>G p.L702= | Silent (SNP) | VAF 55/272 reads (20%) | catalogued as COSV53945919; called by muse, mutect2, varscan2
- PLIN4 | c.3846C>T p.A1282= (on ENST00000301286; = p.A1297= on NM_001367868.2) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs752107866, COSV56682763; called by muse, mutect2, varscan2
- PRDM16 | c.831C>T p.S277= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as rs1278770328, COSV54589879; called by muse, mutect2, varscan2
- PREX2 | c.987G>A p.K329= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV55769250; called by muse, mutect2, varscan2
- RET | c.834C>T p.T278= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs41306550, COSV60694077; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNASEL | c.738A>C p.A246= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV62376800; called by muse, mutect2, varscan2
- SCAMP4 | c.297C>T p.A99= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs766266554, COSV60191089; called by muse, mutect2
- SNED1 | c.1305G>A p.S435= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1462684576; called by muse, mutect2, varscan2
- SRSF1 | c.36G>A p.G12= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV51964979; called by muse, mutect2, varscan2
- UTP4 | c.1887A>G p.E629= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV58732762; called by muse, mutect2, varscan2
- ZNF426 | c.840C>T p.Y280= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as rs1460999199, COSV53469206; called by muse, mutect2, varscan2
- ZNF514 | c.942G>A p.K314= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV54633995; called by muse, mutect2, varscan2
- MIR124-2 | n.3C>A | RNA (SNP) | VAF 5/28 reads (18%) | catalogued as rs947390952; called by muse, mutect2, varscan2
